Somatic mutation profile of tumor specimen MMRF_2364_1_BM_CD138pos (aliquot MMRF_2364_1_BM_CD138pos_T1_KHS5U_L11247) from MMRF case MMRF_2364, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 51.5 years (18,821 days).
Specimen MMRF_2364_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f2c053a6-5c5f-41b7-bc80-c96af417a5fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2364_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2364_1_PB_WBC_C3_KHS5U_L11248; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e8fdd3c-d230-404d-a331-feb7f997bb4e

The open-access MAF lists 83 somatic variants for this specimen: 34 protein-altering or splice-affecting, 8 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, 3'UTR 21, Intron 12, Silent 8, Frame Shift Del 4, Nonsense Mutation 3, 5'UTR 3, RNA 2, 5'Flank 2, Splice Site 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C6orf118 | c.265del p.E89Sfs*17 | Frame Shift Del (DEL) | VAF 54/196 reads (28%) | catalogued as COSV99038779; called by mutect2, pindel, varscan2
- EPS15 | c.1472C>A p.S491* | Nonsense Mutation (SNP) | VAF 12/117 reads (10%) | catalogued as COSV65542761; called by muse, mutect2, varscan2
- IGHJ5 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | PolyPhen benign (0.013); catalogued as rs782001369; called by muse, varscan2
- IGHV2-70 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.37); catalogued as rs192620545; called by muse, mutect2, varscan2
- IGLV3-1 | c.147A>T p.K49N | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs375768240; called by muse, varscan2
- NCAN | c.959C>A p.T320K | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as rs763542211, COSV53059099; called by muse, mutect2
- NDN | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 8/159 reads (5%) | catalogued as COSV100086478; called by muse, mutect2
- PCDHGA3 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.01); catalogued as COSV53923997; called by muse, mutect2, varscan2
- PMCH | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.796); catalogued as rs1205453561; called by muse, mutect2, varscan2
- SP9 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.567); catalogued as rs1033198944; called by muse, mutect2, varscan2
- SYT9 | c.1135T>A p.L379I | Missense Mutation (SNP) | VAF 46/234 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59616253; called by muse, mutect2, varscan2
- TGM7 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 32/597 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1367052982, COSV71772554; called by muse, mutect2
- TRAF3IP3 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372493792, COSV50554720; called by muse, mutect2, varscan2
- TTC21B | c.3192A>G p.I1064M | Missense Mutation (SNP) | VAF 47/184 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs376284506; called by muse, mutect2, varscan2
- ZC3H15 | c.86T>A p.F29Y | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1198343500; called by muse, mutect2, varscan2
- BCAS1 | c.610C>A p.Q204K | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT tolerated (0.96); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- CLN8 | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.572); called by muse, mutect2
- DIPK1C | c.181C>G p.R61G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- EYS | c.2564T>A p.L855Q | Missense Mutation (SNP) | VAF 50/253 reads (20%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- HERC1 | c.10834G>T p.E3612* | Nonsense Mutation (SNP) | VAF 30/306 reads (10%) | called by muse, mutect2
- IARS2 | c.1888G>C p.G630R | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRAG1 | c.661G>C p.V221L | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2
- LTB | c.181C>G p.P61A | Missense Mutation (SNP) | VAF 125/486 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MORC1 | c.185T>C p.M62T | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MRPL20 | c.219_220del p.A74Cfs*2 | Frame Shift Del (DEL) | VAF 29/112 reads (26%) | called by mutect2, pindel, varscan2
- NEB | c.11157G>T p.K3719N | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- OR52E8 | c.724del p.A242Lfs*13 | Frame Shift Del (DEL) | VAF 32/121 reads (26%) | called by mutect2, pindel, varscan2
- PCDHGC5 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- PRDM16 | c.3284+1G>C p.X1095_splice | Splice Site (SNP) | VAF 25/137 reads (18%) | called by muse, mutect2, varscan2
- PRKCD | c.1301A>G p.D434G | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TXNDC5 | c.1223_1240del p.V408_G413del | In Frame Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, pindel, varscan2
- UTP6 | c.978del p.W326* | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- VPS16 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF534 | c.962G>A p.S321N (on ENST00000332323 / NM_001143939.3; = p.S308N on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CACNA1E | c.2049C>T p.F683= | Silent (SNP) | VAF 31/88 reads (35%) | catalogued as COSV62384035, COSV62387912; called by muse, mutect2, varscan2
- FAT3 | c.12015C>T p.F4005= | Silent (SNP) | VAF 6/112 reads (5%) | catalogued as rs1462203233, COSV53103940; called by muse, mutect2
- GPR61 | c.486G>C p.V162= | Silent (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- OR4X1 | c.558C>T p.A186= | Silent (SNP) | VAF 57/347 reads (16%) | catalogued as rs760238000; called by muse, mutect2, varscan2
- PAAF1 | c.147A>C p.P49= | Silent (SNP) | VAF 35/227 reads (15%) | called by muse, mutect2, varscan2
- RPRD2 | c.762G>A p.V254= | Silent (SNP) | VAF 15/279 reads (5%) | called by muse, mutect2
- SEMA6C | c.2493C>A p.A831= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- ZNRF4 | c.600C>T p.Y200= | Silent (SNP) | VAF 40/337 reads (12%) | catalogued as rs924236282, COSV55773261; called by muse, mutect2, varscan2
- AC098582.1 | c.*938C>A | 3'UTR (SNP) | VAF 24/235 reads (10%) | called by muse, mutect2, varscan2
- ADPGK | c.841-154G>A | Intron (SNP) | VAF 10/95 reads (11%) | called by muse, mutect2
- BCL7A | chr12:122021492 C>G | 5'Flank (SNP) | VAF 25/94 reads (27%) | catalogued as COSV55846308, COSV55846472; called by muse, mutect2, varscan2
- C5orf66-AS2 | n.1833G>C | RNA (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- CCDC121 | c.*984A>G | 3'UTR (SNP) | VAF 3/27 reads (11%) | catalogued as rs1206347216; called by muse, mutect2
- CFAP92 | c.*325C>T | 3'UTR (SNP) | VAF 44/242 reads (18%) | called by muse, mutect2
- CHL1 | chr3:407930 A>G | 3'Flank (SNP) | VAF 9/108 reads (8%) | called by muse, mutect2
- CNOT2 | c.1392-966T>A | Intron (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- EFCAB5 | c.*235A>T | 3'UTR (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- EIF4H | c.*472A>G | 3'UTR (SNP) | VAF 102/466 reads (22%) | called by muse, mutect2, varscan2
- EYA2 | c.979-2144_979-2136del | Intron (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- FP565260.6 | c.*2665T>C | 3'UTR (SNP) | VAF 7/53 reads (13%) | catalogued as rs1323872289; called by muse, mutect2
- GLO1 | c.*478C>G | 3'UTR (SNP) | VAF 10/52 reads (19%) | called by muse, mutect2, varscan2
- GLS2 | chr12:56488370 G>A | 5'Flank (SNP) | VAF 9/41 reads (22%) | catalogued as rs1426293016; called by muse, mutect2, varscan2
- H2BC18 | c.378-9498A>T | Intron (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- HOMER1 | c.*1684A>T | 3'UTR (SNP) | VAF 11/72 reads (15%) | called by muse, mutect2, varscan2
- IGF1R | c.*2421_*2422insG | 3'UTR (INS) | VAF 8/65 reads (12%) | called by mutect2, pindel, varscan2
- IQCH | c.387+27450C>A | Intron (SNP) | VAF 17/153 reads (11%) | called by muse, mutect2, varscan2
- KCNA3 | c.*229_*232del | 3'UTR (DEL) | VAF 6/60 reads (10%) | called by mutect2, pindel
- LTB | c.209-91C>A | Intron (SNP) | VAF 35/128 reads (27%) | catalogued as COSV59864690; called by muse, mutect2, varscan2
- MIR154 | n.75T>C | RNA (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- MSANTD1 | c.*516G>A | 3'UTR (SNP) | VAF 21/74 reads (28%) | called by muse, mutect2
- NIPA1 | c.*124G>A | 3'UTR (SNP) | VAF 64/527 reads (12%) | called by muse, mutect2, varscan2
- PACRG | c.613+89858C>T | Intron (SNP) | VAF 6/38 reads (16%) | catalogued as rs1211232014; called by muse, mutect2, varscan2
- PARVB | c.713-44G>A | Intron (SNP) | VAF 12/65 reads (18%) | catalogued as rs757890614; called by muse, mutect2, varscan2
- PCDHA9 | c.2394+153C>T | Intron (SNP) | VAF 13/56 reads (23%) | called by muse, mutect2, varscan2
- RBM19 | c.*181G>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | catalogued as rs1210107301; called by muse, mutect2, varscan2
- REEP3 | c.*1074C>T | 3'UTR (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
- SCN3A | c.*2578A>G | 3'UTR (SNP) | VAF 22/130 reads (17%) | called by muse, mutect2, varscan2
- SGTB | c.*4032T>C | 3'UTR (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2, varscan2
- SH3GL1 | c.-34G>C | 5'UTR (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2
- SLC4A4 | c.-1-10A>C | Intron (SNP) | VAF 120/229 reads (52%) | called by muse, mutect2, varscan2
- SLITRK6 | c.*79A>G | 3'UTR (SNP) | VAF 169/208 reads (81%) | called by muse, mutect2, varscan2
- SNX13 | c.441-6527A>T | Intron (SNP) | VAF 22/110 reads (20%) | called by muse, mutect2, varscan2
- SS18L1 | c.*560G>A | 3'UTR (SNP) | VAF 19/40 reads (48%) | catalogued as rs983034259; called by muse, mutect2, varscan2
- TNRC6B | c.*6768A>G | 3'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- TRPM8 | c.942+352T>C | Intron (SNP) | VAF 32/112 reads (29%) | called by muse, mutect2, varscan2
- UPK1B | c.*473T>G | 3'UTR (SNP) | VAF 19/124 reads (15%) | called by muse, mutect2, varscan2
- VEZF1 | c.-7C>A | 5'UTR (SNP) | VAF 13/37 reads (35%) | called by muse, mutect2, varscan2
- YTHDC1 | c.-249A>G | 5'UTR (SNP) | VAF 34/286 reads (12%) | called by muse, mutect2, varscan2
- ZNF382 | c.*84T>C | 3'UTR (SNP) | VAF 47/185 reads (25%) | called by muse, mutect2, varscan2
